Gene-level copy-number profile of tumor specimen TCGA-AN-A04C-01A from TCGA case TCGA-AN-A04C, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.6 years (18,851 days).
Specimen TCGA-AN-A04C-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.87d149dc-fcf5-4c2b-8c3e-f866ed274cee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A04C-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aa346ee6-2993-49af-9fee-3e5c791409ad

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,852; copy number 2: 7,975; copy number 3: 18,626; copy number 4: 21,854; copy number 5: 5,028; copy number 6: 2,041; copy number 7: 634; copy number 8: 262; copy number 9: 237; copy number 10: 428; copy number 11: 101; copy number 12: 84; copy number 13: 156; copy number 14: 1; copy number 15: 38; copy number 16: 177; copy number 17: 33; copy number 18: 109; copy number 20: 24; copy number 21: 35; copy number 22: 16; copy number 23: 28; copy number 24: 3; copy number 27: 36; copy number 28: 19; copy number 31: 8; copy number 35: 4; copy number 49: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A04C-01A-21D-A036-01): tumor purity 0.64, ploidy 3.55, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,541 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:139,411,927–154,753,120, 240 genes, copy number 11–18 (within-gene range 7–18) (broad region; genes not listed).
- chr4:155,758,992–157,824,256, 26 genes, copy number 10–15: GUCY1B1, ASIC5, TDO2, CTSO, FTH1P21, AC096736.3, LINC02272, AC096736.2, AC096736.1, PDGFC, AC092608.1, AC092608.3, AC092608.2, AC093325.1, RPPH1-3P, Y_RNA, GLRB, RNU6-582P, GRIA2, AC112240.1, AC093817.2, LINC02433, AC093817.1, Y_RNA, AC017037.1, AC017037.3.
- chr4:158,201,604–158,672,255, 8 genes, copy number 10 (within-gene range 8–10): TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46.
- chr4:168,092,537–168,537,786, 5 genes, copy number 16: ANXA10, AC068989.1, DDX60, DDX60L, AC079926.1.
- chr4:168,598,240–168,648,587, 2 genes, copy number 16: BTF3L4P4, PALLD-AS1.
- chr6:106,304,176–109,878,098, 82 genes, copy number 9–13 (within-gene range 6–13) (broad region; genes not listed).
- chr6:134,897,874–136,550,819, 33 genes, copy number 9–27 (within-gene range 1–27): MEMO1P2, ALDH8A1, AL445190.1, HBS1L, MIR3662, AL353596.1, MYB, MYB-AS1, MIR548A2, AL023693.1, AHI1, AL049552.1, AL049552.2, Y_RNA, LINC00271, GAPDHP73, AL035604.1, HMGB1P17, AL133319.1, PDE7B, AL360178.1, AL360178.2, AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4, MAP7, AL023284.3, AL023284.2, NDUFS5P1.
- chr6:137,784,374–137,784,486, 1 gene, copy number 11: Y_RNA.
- chr6:138,088,505–138,107,419, 1 gene, copy number 14: PERP.
- chr6:139,938,864–140,205,326, 4 genes, copy number 15 (within-gene range 1–15): AL050338.2, AL357146.1, RNA5SP220, MIR3668.
- chr6:144,036,618–144,853,034, 9 genes, copy number 16–35 (within-gene range 3–35): AL109755.1, SF3B5, MRPL42P3, STX11, TPT1P4, AL024474.1, UTRN, AL024474.2, AL590704.1.
- chr6:145,735,570–145,887,430, 7 genes, copy number 17 (within-gene range 6–17): AL023806.1, AL023806.2, AL023806.5, AL023806.4, AL023806.3, FBXO30, FBXO30-DT.
- chr6:147,660,703–153,347,488, 116 genes, copy number 9–49 (within-gene range 6–49) (broad region; genes not listed).
- chr8:71,448,811–77,014,028, 91 genes, copy number 10 (broad region; genes not listed).
- chr8:92,972,575–93,700,433, 9 genes, copy number 9 (within-gene range 8–9): IRF5P1, MIR8084, C8orf87, LINC00535, AC016885.1, AC016885.3, AC016885.2, RNA5SP274, ZNF317P1.
- chr8:102,125,432–134,881,899, 420 genes, copy number 9–27 (broad region; genes not listed).
- chr8:137,809,444–139,704,109, 11 genes, copy number 24–31 (within-gene range 2–31): AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9.
- chr17:39,404,285–39,877,896, 19 genes, copy number 28 (within-gene range 2–28): MED1, CDK12, RNU6-233P, AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2.
- chr17:41,665,566–41,930,542, 15 genes, copy number 18 (within-gene range 2–18): AC130686.1, EIF1, GAST, HAP1, RNA5SP442, RN7SL399P, JUP, P3H4, FKBP10, NT5C3B, KLHL10, AC125257.1, KLHL11, ACLY, AC125257.2.
- chr17:44,345,246–44,389,649, 4 genes, copy number 11: GRN, FAM171A2, RPL7L1P5, ITGA2B.
- chr17:44,409,059–44,409,358, 1 gene, copy number 11: RN7SL258P.
- chr17:48,479,097–48,606,414, 11 genes, copy number 11 (within-gene range 7–11): Y_RNA, HOXB1, HOXB2, HOXB-AS1, HOXB3, HOXB-AS3, HOXB-AS2, HOXB4, AC103702.1, MIR10A, HOXB5.
- chr17:51,630,313–52,535,701, 3 genes, copy number 12–13 (within-gene range 6–13): CA10, AC002090.1, LINC01982.
- chr17:55,719,627–55,872,939, 3 genes, copy number 9–13: TMEM100, PCTP, AC090618.1.
- chr19:30,946,582–35,684,201, 164 genes, copy number 9 (broad region; genes not listed).
- chr19:36,259,540–41,425,002, 256 genes, copy number 10 (within-gene range 5–10) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,852. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
